Gene-level copy-number profile of tumor specimen HCM-CSHL-0085-C24-06A from HCMI case HCM-CSHL-0085-C24, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Ampulla of Vater; AJCC pathologic stage: Stage IIIB; Tumor grade: G3; Age at diagnosis: 56.0 years (20,466 days).
Specimen HCM-CSHL-0085-C24-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file c1f7a170-1d94-41ca-9464-cec9eec3dbb1.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HCM-CSHL-0085-C24-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,705 have no estimate.
https://portal.gdc.cancer.gov/files/5d6fe23c-547b-47c0-bb39-d1edd37b3370

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 4; copy number 1: 3,341; copy number 2: 47,780; copy number 3: 7,735; copy number 4: 49; copy number 5: 6; copy number 6: 2; copy number 8: 1.

Homozygous deletions (total copy number 0; autosomes only): 2 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:196,774,813–196,795,407, 1 gene: CFHR3.
- chr5:121,040,090–121,044,032, 1 gene: AC008565.1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 9 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:143,784,376–143,934,776, 9 genes, copy number 5–8 (within-gene range 2–8): AC239800.3, LINC02591, RNU1-143P, AC239798.1, AC239798.2, FCGR1CP, H2BP2, H3-2, AC246680.1.

Autosomal genes at a single copy (total copy number 1): 1,956. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
